Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9SL, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9SL-01A (Primary Tumor).

[page 1 of 5]
Collected

Ordered by

Location

CLINICAL DIAGNOSIS:

High-grade poorly differentiated bladder cancer

FINAL DIAGNOSIS:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- NO HIGH-GRADE UROTHELIAL ATYPIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- NO HIGH-GRADE UROTHELIAL ATYPIA OR MALIGNANCY IDENTIFIED

APICAL URETHRAL MARGIN (C):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN PROSTATIC PARENCHYMA

- NO MALIGNANCY IDENTIFIED

ICD-C 3
carcinoma, urothelial NOS 8120/3
carcinoma, transitional cell NOS 8120/3
Site Bladder NOS C67.9
Dom y bladder C67.1
708120/14

URINARY BLADDER AND PROSTATE AND PERIVESICAL NODES (D):

- INVASIVE TRANSITIONAL CELL CARCINOMA (4.1 x 1.2 x 1.5 CM), GRADE III/IV, EXTENDING TO THE BLADDER DOME WALL TO INVOLVE PERIVESICAL SOFT TISSUE AND PERITONEUM
- EXTENSIVE LYMPHOVASCULAR SPACE AND PERINEURAL INVASION IDENTIFIED
- NO IN SITU CARCINOMA (FLAT LESION) IDENTIFIED
- MULTIPLE SATELLITE TUMOR NODULES ARE IDENTIFIED IN THE PERIVESICAL SOFT TISSUE

RADIAL SURGICAL MARGINS ARE FREE OF TUMOR

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE PERIVESICAL LYMPH NODES (0/3)

PROSTATE:

- FOCAL PROSTATIC INTRAEPITHELIAL NEOPLASM (PIN II AND III) IDENTIFIED
- NO PROSTATIC ADENOCARCINOMA IDENTIFIED

ADDITIONAL LEFT DISTAL URETER (E):

- NO HIGH-GRADE UROTHELIAL ATYPIA OR MALIGNANCY IDENTIFIED

RIGHT PERIAORTIC LYMPH NODES (F):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT COMMON ILIAC LYMPH NODES (G):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT EXTERNAL ILIAC LYMPH NODES (H):

- NO METASTATIC CARCINOMA IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

RIGHT OBTURATOR LYMPH NODES (I):

- METASTATIC CARCINOMA IDENTIFIED IN ONE OF ELEVEN LYMPH NODES EXAMINED (1/11)

RIGHT LYMPH NODE OF CLOQUET (J):

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT PERIAORTIC LYMPH NODES (K):

- FIBROADIPOSE TISSUE

[page 2 of 5]
Case:

Collected:

Ordered by:

Location:

- NO LYMPH NODES IDENTIFIED

LEFT COMMON ILIAC LYMPH NODES (L):

- METASTATIC CARCINOMA IDENTIFIED IN TWO OF SEVEN LYMPH NODES EXAMINED
(2/7)

LEFT LYMPH NODE OF CLOQUET (M):

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT EXTERNAL ILIAC LYMPH NODES (N):

- METASTATIC CARCINOMA IDENTIFIED IN THREE OF FOUR LYMPH NODES EXAMINED
(3/4)

LEFT OBTURATOR LYMPH NODES (O):

- NO METASTATIC CARCINOMA IDENTIFIED IN ELEVEN LYMPH NODES EXAMINED (0/11)

PRESACRAL LYMPH NODES (P):

- NO METASTATIC CARCINOMA IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

LEFT PROXIMAL URETER (Q):

- NO HIGH-GRADE UROTHELIAL ATYPIA OR MALIGNANCY IDENTIFIED

RIGHT PROXIMAL URETER (R):

- NO HIGH-GRADE UROTHELIAL ATYPIA OR MALIGNANCY IDENTIFIED

PATHOLOGIC TNM STAGE: pT3aN2MX

INTRAOPERATIVE DIAGNOSIS:

FROZEN SECTION DIAGNOSIS:

AFS: Right distal ureter:

- no tumor identified

BFS: Left distal ureter:

- no tumor identified

CFS: Apical urethral margin:

- no tumor identified

GROSS DESCRIPTION:

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter F/S." It consists of a segment of ureter measuring 0.3 cm in length by 0.5 cm in diameter. The specimen is entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter F/S." It consists of a segment of ureter measuring 0.4 cm in length by 0.6 cm in diameter. The specimen is entirely submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and labeled "Apical urethral margin F/S." It consists of a fragment of pink-tan soft tissue measuring 1.5 x 1.5 x 0.3 cm. The specimen is entirely submitted for frozen section in cassette CFS.

D: The specimen is received fresh from the O.R. and labeled "Urinary bladder & prostate & perivesicle nodes." It consists of a bladder with associated prostate and perivesical fatty tissue measuring overall 26 x 14 x 4 cm. The peritoneum measures 20 x 10 x 0.8 cm. The bladder measures 9.5 x 7.5 x 2 cm. There is an exophytic mass lesion measuring 1.7 x 1 x 1.5 cm, located at the mid to left dome, adjacent to the mass lesion, there is an erythematous, ulcerative area measuring

[page 3 of 5]
Collected:

Ordered by:

Location:

2.4 x 1.2 cm. Sectioning through the mass lesion reveals the tumor grossly invades through the muscularis propria into perivesical fatty tissue. The uninvolved wall of the bladder measures 0.9 cm in thickness. The left ureter measures 1.5 cm in length by 0.6 cm in circumference, and the right distal ureter measures 3.5 cm in length by 0.6 cm in circumference. The prostate measures 5.5 x 4.5 x 4 cm. The left vas deferens measures 11 cm in length by 0.6 cm in diameter, and the right vas deferens measures 4 cm in length by 0.6 cm in diameter. The left seminal vesicle measures 3.5 x 2 x 1 cm, and the right seminal vesicle measures 3 x 1.5 x 1 cm. The prostatic urethra measures 3 cm in length by 1.7 cm in diameter. The verumontanum measures 1.5 x 0.6 x 0.4 cm. The surgical margin is entirely inked black. Multiple candidate perivesical lymph nodes are identified. Representative sections are submitted in 25 cassettes.

E: The specimen is received fresh from the O.R. and labeled "Additional L distal ureter." It consists of a segment of ureter with periureteral fatty tissue measuring overall 6 x 3 x 1 cm. The ureter measures 4 cm in length by 0.6 cm in diameter. Representative sections are submitted in one cassette.

F: The specimen is received in formalin and labeled "Right peri aortic lymph nodes." It consists of two fragments of yellow-tan soft tissue measuring 3 x 2 x 1 cm. The specimen is entirely submitted in two cassettes.

G: The specimen is received in formalin and labeled "Right common iliac lymph nodes." It consists of multiple fragments of yellow-tan soft tissue measuring 2.5 x 2 x 0.5 cm in aggregate. The specimen is entirely submitted in one cassette.

H: The specimen is received in formalin and labeled "Right external iliac lymph nodes." It consists of multiple fragments of yellow-tan soft tissue measuring 5 x 4 x 1.5 cm in aggregate. Multiple lymph nodes are identified. The largest one measuring 1.5 cm in greatest dimension. The specimen is entirely submitted in four cassettes.

I: The specimen is received in formalin and labeled "Right obturator lymph nodes." It consists of multiple fragments of yellow-tan soft tissue measuring 5 x 3.5 x 2 cm in aggregate. Multiple lymph nodes are identified. The specimen is entirely submitted in five cassettes.

J: The specimen is received in formalin and labeled "Right lymph node of cloquet." It consists of a fragment of yellow-tan soft tissue measuring 4 x 2 x 1 cm in aggregate. Two lymph nodes are identified with the largest one measuring 2 cm in greatest dimension. The lymph nodes are bisected and the specimen is entirely submitted in one cassette.

K: The specimen is received in formalin and labeled "Left peri aortic lymph nodes." It consists of a fragment of yellow-tan soft tissue measuring 3 x 2 x 0.5 cm. The specimen is entirely submitted in one cassette.

L: The specimen is received in formalin and labeled "Left common iliac lymph nodes." It consists of multiple fragments of yellow-tan soft tissue measuring 2 x 2 x 0.5 cm. Multiple lymph nodes are identified. The specimen is entirely submitted in one cassette.

M: The specimen is received in formalin and labeled "Left lymph node of cloquet." It consists of a fragment of yellow-tan soft tissue measuring 2.5 x 1.5 x 0.8 cm in aggregate. Two lymph nodes are identified. The specimen is entirely submitted in one cassette.

N: The specimen is received in formalin and labeled "Left external iliac lymph nodes." It consists of multiple fragments of yellow-tan soft tissue measuring 3 x 3 x 1 cm in aggregate. Multiple lymph nodes are identified with the largest one

[page 4 of 5]
Collected:	
Ordered by:	Location:

measuring 1.5 cm in greatest dimension. The specimen is entirely submitted in one cassette.

O: The specimen is received in formalin and labeled "Left obturator lymph nodes." It consists of multiple fragments of yellow-tan soft tissue measuring 8 x 6 x 2 cm in aggregate. Multiple lymph nodes are identified with the largest one measuring 2.7 cm in greatest dimension. The specimen is entirely submitted in five cassettes.

P: The specimen is received in formalin and labeled "Presacral lymph nodes." It consists of multiple fragments of yellow-tan soft tissue measuring 4 x 2.5 x 1 cm in aggregate. Multiple lymph nodes are identified. The specimen is entirely submitted in one cassette.

Q: The specimen is received in formalin and labeled "Left proximal ureter." It consists of a segment of ureter measuring 1 cm in length by 0.3 cm in diameter. There is one metallic clip located closest to one end of the ureter indicating the proximal margin. The proximal margin is shaved and entirely submitted in one cassette.

R: The specimen is received in formalin and labeled "Right proximal ureter." It consists of a segment of ureter measuring 1 cm in length by 0.3 cm in diameter. One metallic clip is noted located closest to the proximal margin. The proximal margin is shaved and entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
CFS: frozen section, apical urethral margin
D1-4: tumor with deepest invasion
D5: left ureterovesical junction
D6: right ureterovesical junction
D7: left trigone
D8: left lateral
D9: right dome
D10: right lateral
D11: right trigone
D12: right distal prostate
D13: left distal prostate
D14: right midprostate
D15: left midprostate
D16: right proximal prostate
D17: left proximal prostate
D18-25: possible perivesical lymph nodes
E: additional left distal ureter
F1,2: right periaortic lymph nodes
G: right common iliac lymph nodes
H1: one lymph node, bisected
H2-4: lymph nodes
I1-5: right obturator lymph nodes
J: right lymph node of Cloquet
K: left periaortic lymph nodes
L: left common iliac lymph nodes
M: left lymph node of Cloquet
N: left external iliac lymph nodes
O1: one lymph node, bisected
O2-5: lymph nodes
P: presacral lymph nodes
Q: left proximal ureter
R: right proximal ureter

[page 5 of 5]
REPORT

Collected

Ordered by

MICROSCOPIC DESCRIPTION:

A-C: See microscopic-diagnoses.

D: Sections of the exophytic mass lesion and adjacent ulcerated lesion seen grossly on the mid to left dome region correspond histologically to invasive transitional cell carcinoma (D2, D3, D4). The neoplastic cells have high NC ratio with large pleomorphic hyperplastic nuclei and are arranged in solid sheets and single cells. Extensive desmoplastic change is seen. The tumor extends through the muscularis propria into the perivesical soft tissue to involve the peritoneum. Multiple satellite tumor nodules are identified in the perivesical soft tissue. No carcinoma in situ is identified. Extensive lymphovascular space invasion is seen. Sections of the prostate show focal prostatic intraepithelial neoplasm (PIN II and III) characterized by hyperplastic glands lined by stratified layers of enlarged cells with corresponding large nuclei and variable prominent nucleoli.

E-R: See microscopic-diagnoses.

Signed by:

ELECTRONIC SIGNATURE

POST-OPERATIVE DIAGNOSIS:

Same

PRE-OPERATIVE DIAGNOSIS:

Same

ORDERING PHYSICIAN:

Ordering Physician:

Source: NCI Genomic Data Commons file a6acb957-8630-46cb-a862-f3cfc90e786e (TCGA-XF-A9SL.D8FA25D2-8119-47BA-8ECD-A2EA6E56E7B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).